FM case AD8096 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mucoepidermoid Neoplasms; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/e3b63599-85f1-4f8b-b596-5e857e2f7cba

Male, 73.0 years: Mucoepidermoid carcinoma (ICD-O-3 8430/3) of the head, face or neck; specimen biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
